Somatic mutation profile of tumor specimen 0DSPLV from CCDI case PBCINL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Spinal cord; Age at diagnosis: 7.0 years (2,575 days).
Specimen 0DSPLV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26900d3a-458e-40ed-8c59-95313d387128.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSPM2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/975bd360-9124-43b5-8144-1dcb605820dc

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 3, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GRN | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 198/567 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs768333369, CD063535; called by muse, mutect2, varscan2
- IGF2R | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 342/975 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs778725774, COSV63626464; called by muse, mutect2, varscan2
- TMEM26 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 354/903 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777459941; called by muse, mutect2, varscan2
- ATXN7L2 | c.1861G>T p.V621L | Missense Mutation (SNP) | VAF 242/615 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DMD | c.10555A>G p.N3519D | Missense Mutation (SNP) | VAF 209/536 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- FAT1 | c.5392G>A p.D1798N | Missense Mutation (SNP) | VAF 309/832 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQCM | c.359G>A p.C120Y | Missense Mutation (SNP) | VAF 334/959 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRC2 | c.1240G>T p.G414C | Missense Mutation (SNP) | VAF 209/481 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NCOR1 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 396/1103 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- TNRC6A | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 132/663 reads (20%) | called by muse, mutect2, varscan2
- ADNP2 | c.1971C>T p.P657= | Silent (SNP) | VAF 216/559 reads (39%) | catalogued as rs141229292; called by muse, mutect2, varscan2
- CDC42EP1 | c.615A>G p.S205= | Silent (SNP) | VAF 168/426 reads (39%) | called by muse, mutect2, varscan2
- GGT1 | c.1482C>T p.D494= | Silent (SNP) | VAF 198/903 reads (22%) | catalogued as rs372817273, COSV99958867; called by muse, mutect2, varscan2
- GPNMB | c.1559+30A>G | Intron (SNP) | VAF 318/842 reads (38%) | catalogued as rs531800146; called by muse, mutect2, varscan2
- KDM1A | c.2099-49G>T | Intron (SNP) | VAF 136/337 reads (40%) | called by muse, mutect2, varscan2
- MICU1 | c.537+9802C>T | Intron (SNP) | VAF 117/306 reads (38%) | called by muse, mutect2, varscan2
